CCDI case PBCKGE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/743587a7-b41c-49ea-8ac3-39d18b4f63c1

Demographics
Sex at birth: female.

Diagnoses (1)
1. Neoplasm, uncertain whether benign or malignant: ICD-O-3 morphology code: 8000/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.7 years (1,353 days).

Biospecimens (3 samples)
- Sample 0DU3KF: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DU3KV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DU3MJ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
